MMRF case MMRF_2646 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4a765ee5-4a21-45ac-add3-9a6b0206e860

Demographics
Sex at birth: male; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.8 years (20,760 days); ISS stage: II; Days to last known disease status: 154 days; Days to last follow up: 154 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -7, day 154.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 3550 mg/dL.
- Calcium 2.8 mmol/L.
- Platelets 206 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 12 mg/dL.
- M Protein 0.29 g/dL.
- Beta 2 Microglobulin 3.6 µg/mL.
- Creatinine 150 µmol/L.
- Absolute Neutrophil 4.77 ×10⁹/L.
- Albumin 43 g/L.
- Hemoglobin 6.94 mmol/L.
- Lactate Dehydrogenase 7.42 µkat/L.

Other clinical attributes
- Day -7: Weight: 170 kg; Height: 80 cm.

Biospecimens (2 samples)
- Sample MMRF_2646_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2646_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
